Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84B, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84B-01A (Primary Tumor).

[page 1 of 3]
Ref by

Sex Male

Requested
Collected
Received
Printed

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

Seizures with radiographic progression of non-enhancing tumour (query high-grade glioma).

MACROSCOPIC:

'Brain tumour'. The specimen consists of irregular fragments of variegated tissue 50x50x5mm in aggregate. All embedded.
(Blocks A to C)

MICROSCOPIC:

STRUCTURED REPORT FOR TUMOURS OF THE CENTRAL NERVOUS SYSTEM

Adapted from Tumours of the Central Nervous System Structured Reporting Protocol based on WHO classification 2007, 4th Edition. First Edition 2011.
Copyright

CLINICAL SUMMARY:

Date of Birth/Age:
Sex:
Requesting Clinician:
Treating Clinician(s):
Clinical history on request form:

Ancillary tests requested:
Other clinical history-source:

Unknown
Seizures with radiographic progression of non-enhancing tumour (? high grade glioma)
Nil
Letter by neurosurgical fellow, Dr [redacted] on behalf of [redacted] which states that the patient had a tonic clonic seizure in [redacted] with an MRI at that time demonstrating a left parietal lesion possibly consistent with a low grade glioma. Over the last few months the MRI has shown that the lesion has grown slightly with some 'wispy enhancement'.

See above
See above
Nil
Anti-epileptic drug
Unknown
'Wispy enhancement'

Presenting symptoms:
Duration of symptoms:
Previous tumour history:
Current and previous treatment:
Family history:
Imaging findings:
Anatomical site of lesion/s:
Intra-axial:
Laterality of tumour:
Reason for biopsy:
Clinical diagnosis or differential diagnosis:

Parietal
Left
Diagnosis

Nil

Surgeon
Use

☐ Normal

☐ No-Action
File

☐ Contact
Patient

☐ See
Patient

☐ See File

☐ Continuing
Treatment

ICD-O-3
Astrocytoma, grade III
Site Brain, supratentorial NOS
Date 10/30/13
C71.3
C71.3
C71.3

MACROSCOPIC SPECIMEN SUMMARY:

Specimen type(s):
Number of specimens:
Dimensions:
Specimen received in:
Amount of unprocessed tissue: Nil

Resection
Multiple
50x50x5mm
Formalin

[page 2 of 3]
Ref by

DOB
Sex

Requested
Collected :
Received :
Printed

MICROSCOPIC FEATURES:

Microscopic description:

The tumour is highly cellular and composed of enlarged pleomorphic ovoid and angulated cells with hyperchromatic nuclei. Some gemistocytic tumour cells are also present. The tumour is associated with some microcystic change focally and there is also quite prominent calcification present amongst the tumour cells. On low power also there is a fine vascular pattern with an almost chicken wire architecture. There is no evidence of necrosis and no evidence of endothelial proliferation.

Proliferation index (Ki67):

20%

p53:

15%

IDH1:

Negative

Mitoses:

7/10HPF on H&E alone. In areas, on a PHH3 stain, the mitotic rate is assessed as up to 24 per 10 HPF.

Specimen comment:

Diagnostic

IMMUNOHISTOCHEMICAL STAINS:

Negative:

Blocks: A, B & C
IDH1

MOLECULAR PATHOLOGY AND OTHER TESTING IF REQUIRED:

FISH 1p 19q and EGFR amplification:

Block: C. This is high recommended as whilst the cells cytologically are favoured to represent malignant astrocytic cells, the low power appearance together with the quite prominent calcification and vascular pattern is reminiscent of an oligodendroglioma which in this case would be an anaplastic oligodendroglioma, given the high mitotic rate and pleomorphic nuclei. Awaiting patient agreement for this testing.

MGMT promoter methylation:

Block: B. Tumour 50%

IDH1/IDH2 exon 4 sequencing:

Block: B. Tumour 50% Awaiting patient agreement:

Clinical trials (with ethics):

Block: B. Tumour 50%

Research block requests with ethics approval when no longer required for diagnosis:

Block B:

Note: Any further results will be issued as a supplementary report.

LINEAGE:

Favoured to be astrocytic.

OVERALL COMMENT/SUMMARY:

The histological features are favoured to represent an anaplastic astrocytoma, WHO grade III. As discussed above, there are some histological features which are reminiscent of an oligodendroglioma and for this reason, it is recommended that material is sent for 1p/19q testing.

DIAGNOSTIC SUMMARY:

Specimen type:

Resection left parietal tumour

Tumour site and laterality:

Left parietal

WHO 2007 tumour type:

Astrocytoma (favoured) (see above comments)

WHO 2007 grade:

III

Differential diagnosis:

Anaplastic oligodendroglioma needs to be excluded by relevant molecular pathology (see above)

ICD-0-3 CODE:

Surgeon
Use

Normal

No Action
File

Contact
Patient

See
Patient

See File

Continue
Treatment

Signed

Date

[page 3 of 3]
Ref b:

DOB
Sex

Requester
Collected
Received
Printed

DIAGNOSIS:

LEFT PARIETAL BRAIN LESION

**HISTOLOGICAL FEATURES FAVOURING A DIAGNOSIS OF
ANAPLASTIC ASTROCYTOMA, WHO GRADE III
(SEE ABOVE FOR DIFFERENTIAL DIAGNOSIS)**

Reported b:

Surgeon
Use

Normal

No-Archival
File

Contact
Patient

See
Patient

See File

Continue
Treatment

Signed

Date

Is Completed: Histo. **FINAL REPORT**

ical Notes:

Source: NCI Genomic Data Commons file d00b2f5f-4e37-4545-a1af-169f7dad1228 (TCGA-TM-A84B.011132B0-CA1B-4F19-B338-050E69F2E2FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).